TCGA case TCGA-VR-AA4D — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/02d98b0a-8360-49b9-bbd6-b70c79cbd32d

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 53 years; Vital status: Dead; Days to death: 1,405 days (3.8 years); Country of birth: Brazil.

Diagnoses (4)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 54.0 years (19,714 days); Year of diagnosis: 2010; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC clinical T: T1; AJCC clinical N: NX; AJCC clinical M: M0; AJCC clinical stage: Stage IA; AJCC pathologic T: T1; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,405 days (3.8 years); Cancer detection method: Symptomatic; Esophageal columnar dysplasia degree: Negative/ No Dysplasia; Esophageal columnar metaplasia present: No; Goblet cells columnar mucosa present: No; Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Negative; Lymph nodes positive: 6; Lymph nodes tested: 25.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 166 days; Days to treatment end: 288 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 166 days; Days to treatment end: 288 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 224 days; Days to treatment end: 261 days; Treatment dose: 4,500 cGy; Treatment outcome: Progressive Disease; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Chemotherapy, preoperative; Radiation Therapy, NOS, preoperative.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Lung, NOS. Age at diagnosis: 56.3 years (20,546 days); Days to diagnosis: 832 days (2.3 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Adrenal gland, NOS. Age at diagnosis: 56.3 years (20,546 days); Days to diagnosis: 832 days (2.3 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.
4. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Liver. Age at diagnosis: 56.3 years (20,546 days); Days to diagnosis: 832 days (2.3 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (6 entries)
- Day 832 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 832 days (2.3 years); Evidence of progression type: Convincing Image Source.
- Day 832 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Adrenal gland, NOS; Days to progression: 832 days (2.3 years); Evidence of progression type: Convincing Image Source.
- Day 832 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 832 days (2.3 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 1,378 days (3.8 years); Disease response: With Tumor.
- Days to follow up: 1,405 days (3.8 years); Disease response: With Tumor.
- Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: GERD; Reflux treatment type: No Treatment; Risk factors: GERD.
- Timepoint category: Initial Diagnosis; Weight: 82 kg; Height: 178 cm; BMI: 25.9.

Exposures
- Exposure type: Tobacco.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VR-AA4D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 100 mg.
  Slide TCGA-VR-AA4D-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 35; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-VR-AA4D-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VR-AA4D-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cancer procurement state province: Sao Paulo; Cancer procurement city: Barretos; History neoadjuvant treatment: No; Tumor status: With tumor; Alcohol history documented: No; History reflux disease indicator: Yes; History hpylori infection indicator: Never; History barretts esophageal indicator: No.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Adenocarcinoma, NOS; Esoph non CA degree of dysplasia: Negative/no dysplasia; Method initial path diagnosis: Endoscopic Biopsy; Lymph node sprd radiograph evidence: No; Lymph nodes examined: Yes; Patient to undergo surgery: Surgery already performed.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,405 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,405 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 832 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VR-AA4D-01A-11D-A37B-01): tumor purity 0.74, ploidy 3.47, whole-genome doublings 1.
